Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3434, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3434-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Right Renal Mass, Cholecystitis.

Source of Specimen(s):

A: Gallbladder

B: Right kidney

Gross Description:

Received in two parts.

Source of Tissue: 1. Labeled #1, "gallbladder"

Gross Description: Received fresh with patient identification is a 8.0 x 2.5 x 1.5 cm intact gallbladder having a tan to red-purple from smooth to shaggy outer surface. On opening there is no bile present. No calculi are grossly identified. The mucosa is green-tan and reticulated with the wall averaging 0.2 cm in thickness. Representative sections are submitted in one block.

Designation of Sections: Block 1

Summary of Sections: undesignated-5

Source of Tissue: 2. Labeled #2, "right kidney"

Gross Description: Received fresh with patient identification is a 503 gram right nephrectomy having a moderate amount of attached perinephric fat. There is a 1.5 x 0.3 cm fragment of attached ureter having a lumen, 0.2 cm in greatest dimension which is probe patent to the renal hilum. The kidney itself is 12.5 x 6.5 x 6.5 cm in greatest dimension. It is bivalved to reveal a mass in the mid portion, 7.0 x 4.5 x 4.0 cm in greatest dimension. The cut surfaces of the mass are golden-yellow-orange to green-tan, smooth and nodular. The remaining renal parenchyma is red-brown, firm having a well-defined cortico-medullary junction. Representative sections are submitted in six blocks.

Designation of Sections: 2A- ureter and vascular margins, 2B-2E- tumor, 2F- random sections kidney

Summary of Sections: multiple

Note: Tissue is Submitted for Cytogenetic Studies.

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Right Renal Mass, Cholecystitis.

Source of Specimen(s):

A: Gallbladder

B: Right kidney

Gross Description:

Received in two parts.

Source of Tissue: 1. Labeled #1, "gallbladder"

Gross Description: Received fresh with patient identification is a 8.0 x 2.5 x 1.5 cm intact gallbladder having a tan to red-purple from smooth to shaggy outer surface. On opening there is no bile present. No calculi are grossly identified. The mucosa is green-tan and reticulated with the wall averaging 0.2 cm in thickness. Representative sections are submitted in one block.

Designation of Sections: Block 1

Summary of Sections: undesignated-5

Source of Tissue: 2. Labeled #2, "right kidney"

Gross Description: Received fresh with patient identification is a 503 gram right nephrectomy having a moderate amount of attached perinephric fat. There is a 1.5 x 0.3 cm fragment of attached ureter having a lumen, 0.2 cm in greatest dimension which is probe patent to the renal hilum. The kidney itself is 12.5 x 6.5 x 6.5 cm in greatest dimension. It is bivalved to reveal a mass in the mid portion, 7.0 x 4.5 x 4.0 cm in greatest dimension. The cut surfaces of the mass are golden-yellow-orange to green-tan, smooth and nodular. The remaining renal parenchyma is red-brown, firm having a well-defined cortico-medullary junction. Representative sections are submitted in six blocks.

Designation of Sections: 2A- ureter and vascular margins, 2B-2E- tumor, 2F- random sections kidney

Summary of Sections: multiple

Note: Tissue is Submitted for Cytogenetic Studies.

[page 3 of 3]
Final Diagnosis:

1. Gallbladder (cholecystectomy):

- Mild chronic cholecystitis.

2. Right kidney (nephrectomy):

- Clear cell adenocarcinoma (7.0 cm), Fuhrman nuclear grade II/IV.
- Tumor confined to kidney.
- Surgical vascular and ureteral margins are free of tumor.

-pT1NxMx.

Procedures/Addenda

FC Cytogenetics Tumor

Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Right Renal Mass

KARYOTYPE: Abnormal karyotype: 42-44,XY,-6,-8[cp5]

RESULTS: The renal mass was sent to a commercial laboratory for cytogenetic analysis. Only five metaphases were available for chromosome count and analysis, and two of these metaphases were karyotyped by G-banding. All five cells were abnormal with loss of chromosomes 6 and 8. The karyotype description is a composite, listing only the consistent clonal changes. Loss of chromosomes 6 and 8 has been reported in a variety of renal tumors including renal cell carcinoma and renal sarcoma.

Source: NCI Genomic Data Commons file b1431062-b938-462f-b9ca-d1a88370f165 (TCGA-AK-3434.AC0D06CB-E75F-424A-A5E6-8A301CA69AD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).